FM case AD16481 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/56d53101-f27d-43be-b779-e12da4b06484

Male, 42.6 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the pleura. Tumor nuclei on the sequenced sample's slide: 25% (pathologist estimate recorded by GDC). Sample type: Tumor.
